Gene-level copy-number profile of tumor specimen HTMCP-03-06-02001-01B from CGCI case HTMCP-03-06-02001, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02001-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5d16643b-3ff4-4a0c-b836-4ebfd642ff94.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02001-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/92cf017f-aaef-4c82-a352-cdf60097cf6d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,633; copy number 2: 50,861; copy number 3: 4,584; copy number 4: 1,259; copy number 5: 50; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 52 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:170,222,424–170,418,615, 5 genes, copy number 5: PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2.
- chr3:172,505,508–172,821,474, 11 genes, copy number 5: TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P.
- chr9:62,532,337–62,534,724, 2 genes, copy number 8: BX005266.2, BX005266.1.
- chr16:32,715,931–32,788,944, 8 genes, copy number 5: AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Autosomal genes at a single copy (total copy number 1): 1,633. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
